Somatic mutation profile of tumor specimen TCGA-ZM-AA0F-01A (aliquot TCGA-ZM-AA0F-01A-21D-A435-10) from TCGA case TCGA-ZM-AA0F, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Seminoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IA; Age at diagnosis: 35.5 years (12,973 days).
Specimen TCGA-ZM-AA0F-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 970cf0fd-537b-483e-8c7a-1c241597e3fc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ZM-AA0F-10A (Blood Derived Normal), aliquot TCGA-ZM-AA0F-10A-01D-A438-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7a4436cb-3b8c-4f9b-a866-1c0ce7fa43e1

The open-access MAF lists 6 somatic variants for this specimen: 4 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 3, Silent 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KIT | c.1694_1720del p.G565_T574delinsA | In Frame Del (DEL) | VAF 20/174 reads (11%) | hotspot (GDC flag); called by mutect2, pindel
- IGSF23 | c.494G>A p.G165E | Missense Mutation (SNP) | VAF 10/224 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.437); catalogued as rs1326190325; called by muse, mutect2
- SATB1 | c.368G>A p.S123N | Missense Mutation (SNP) | VAF 6/99 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.105); called by muse, mutect2
- VRK2 | c.501A>G p.I167M | Missense Mutation (SNP) | VAF 16/632 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- DNAH14 | c.8625T>C p.G2875= (on ENST00000445597; = p.G3678= on NM_001367479.1) | Silent (SNP) | VAF 18/210 reads (9%) | catalogued as COSV59896357; called by muse, mutect2
- TDRD12 | c.801A>G p.Q267= | Silent (SNP) | VAF 32/402 reads (8%) | catalogued as rs772530801; called by muse, mutect2
